Gene-level copy-number profile of tumor specimen TCGA-UF-A7JC-01A from TCGA case TCGA-UF-A7JC, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 42.3 years (15,452 days).
Specimen TCGA-UF-A7JC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.4910323b-9a7c-42f4-966d-4ca395c6ba19.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-UF-A7JC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/29a228d1-39d4-40a6-b3ea-aeb8f7ad838d

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 213; copy number 2: 7,534; copy number 3: 10,033; copy number 4: 32,544; copy number 5: 7,545; copy number 6: 1,234; copy number 7: 112; copy number 8: 158; copy number 9: 16; copy number 10: 141; copy number 11: 88; copy number 15: 45; copy number 20: 109; copy number 21: 38; copy number 27: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-UF-A7JC-01A-21D-A34I-01): tumor purity 0.81, ploidy 1.95, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 445 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:69,294,151–71,997,597, 83 genes, copy number 15–21 (within-gene range 8–21) (broad region; genes not listed).
- chr11:75,815,210–76,144,232, 1 gene, copy number 10 (within-gene range 8–10): UVRAG.
- chr11:75,911,204–91,116,555, 280 genes, copy number 9–20 (broad region; genes not listed).
- chr11:91,184,934–91,185,543, 1 gene, copy number 20: AP003485.2.
- chr11:97,222,644–102,530,750, 42 genes, copy number 20: LINC02553, RNA5SP347, LINC02713, AP003730.1, AP001317.1, AP003038.1, AP003715.1, AP002428.1, CNTN5, RN7SKP53, RPA2P3, RN7SL222P, PPIAP43, ARHGAP42-AS1, ARHGAP42, RN7SKP115, PGR, PGR-AS1, AP001533.1, TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7.
- chr12:630,858–991,190, 7 genes, copy number 27 (within-gene range 3–27): NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1.
- chr12:1,151,810–1,153,059, 1 gene, copy number 27: HTR1DP1.
- chr12:4,097,451–4,909,265, 26 genes, copy number 10: HSPA8P5, AC007207.1, CCND2-AS1, CCND2, AC008012.1, TIGAR, AC006122.1, FGF23, FGF6, C12orf4, RAD51AP1, DYRK4, AC005832.2, AC005832.4, AKAP3, AC005832.3, AC005832.1, NDUFA9, AC005833.1, GAU1, GALNT8, AC005833.2, KCNA6, AC006063.1, AC006063.3, AC006063.4.
- chr12:4,909,905–4,918,256, 1 gene, copy number 10: KCNA1.
- chr12:5,226,196–5,383,653, 3 genes, copy number 9 (within-gene range 5–9): LINC02443, AC006206.2, AC006206.1.

Autosomal genes at a single copy (total copy number 1): 213. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
